National Lung Screening Trial (NLST) participant 205405 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 61 years; Gender: female; Race: Black or African-American; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 36 cm, reconstruction filter GE Standard.
- T1 (day 639): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 30 cm, reconstruction filter GE Standard.
- T2: No screening result: Not Expected - Cancer in screening window.

Abnormalities recorded by the reading radiologist on the CT screens (3 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Emphysema.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 15 mm, longest perpendicular diameter 15 mm; margins poorly defined; predominant attenuation mixed; greatest diameter on CT slice 129; new (not pre-existing on earlier images).
- T1 abnormality 2: Emphysema.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T1; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 791, study year T1. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Primary tumour location: left upper lobe. Histology: bronchiolo-alveolar adenocarcinoma, NOS (ICD-O-3 8250/3). Grade: well differentiated (G1). Tumour size on pathology: 11 mm. AJCC 6th edition staging: stage IA (best stage, from pathologic TNM); clinical T1 N0 M0 (stage IA); pathologic T1 N0 M0 (stage IA). AJCC 7th edition staging: stage IA; clinical T1a N0 M0; pathologic T1a N0 M0. Summary stage: localized.

Follow-up
Last known free of lung cancer: day 791 (for ACRIN participants with lung cancer this field holds the diagnosis date).
